Somatic mutation profile of tumor specimen MMRF_2089_2_BM_CD138pos (aliquot MMRF_2089_2_BM_CD138pos_T1_KHS5U_L12919) from MMRF case MMRF_2089, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.9 years (24,417 days).
Specimen MMRF_2089_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb8464df-4daa-4db2-bc19-45304ac39cfc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2089_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2089_1_PB_WBC_C3_KHS5U_L08822; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02d69a03-54ce-404a-b42f-8af56433e709

The open-access MAF lists 373 somatic variants for this specimen: 151 protein-altering or splice-affecting, 49 silent, 173 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 122, 3'UTR 100, Silent 49, Intron 45, 5'UTR 13, Nonsense Mutation 12, Frame Shift Del 10, RNA 7, 5'Flank 4, 3'Flank 3, Frame Shift Ins 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 57/125 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 42/98 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs764146326, CD137626, CM076566, CM153816, COSV52671054, COSV52674651, COSV52678614; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ACAN | c.6701T>A p.L2234Q | Missense Mutation (SNP) | VAF 137/229 reads (60%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV100718699; called by muse, mutect2, varscan2
- ADGRD1 | c.1079A>G p.H360R | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as rs746975895; called by muse, mutect2, varscan2
- AMOTL1 | c.963G>A p.M321I | Missense Mutation (SNP) | VAF 104/333 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100133830; called by muse, mutect2, varscan2
- ANKRD42 | c.1030T>C p.F344L | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.883); catalogued as COSV52614252; called by muse, mutect2
- APOA2 | c.277C>T p.L93F | Missense Mutation (SNP) | VAF 72/215 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs1215900467; called by muse, mutect2, varscan2
- BTG1 | c.85A>T p.K29* | Nonsense Mutation (SNP) | VAF 30/77 reads (39%) | catalogued as COSV55458809; called by muse, varscan2
- C1orf94 | c.1199G>T p.G400V (on ENST00000488417 / NM_001134734.2; = p.G210V on NM_032884.5) | Missense Mutation (SNP) | VAF 88/179 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100974946; called by muse, mutect2, varscan2
- C3orf62 | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as COSV55539998; called by muse, mutect2, varscan2
- CAT | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs749536831; called by muse, mutect2, varscan2
- CDH7 | c.2245G>C p.D749H | Missense Mutation (SNP) | VAF 72/184 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.606); catalogued as COSV59883694; called by muse, mutect2, varscan2
- COL27A1 | c.2512G>A p.G838S | Missense Mutation (SNP) | VAF 142/237 reads (60%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV61926137; called by muse, varscan2
- CUZD1 | c.454C>G p.P152A | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.053); catalogued as rs558554477; called by muse, mutect2, varscan2
- DFFA | c.526dup p.Q176Pfs*5 | Frame Shift Ins (INS) | VAF 25/100 reads (25%) | catalogued as rs755703182; called by mutect2, pindel, varscan2
- DNAH5 | c.6661G>C p.E2221Q | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.317); catalogued as COSV54235819; called by muse, mutect2, varscan2
- DYNC2H1 | c.6153G>C p.W2051C | Missense Mutation (SNP) | VAF 55/168 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100520050; called by muse, mutect2, varscan2
- EDEM3 | c.2527C>T p.H843Y | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); catalogued as rs1352720434; called by muse, mutect2
- FLG | c.2561G>T p.G854V | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs373305550; called by muse, mutect2, varscan2
- GMPR | c.179C>T p.T60M | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1162015376; called by muse, mutect2, varscan2
- HERC1 | c.6002A>T p.K2001I | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs866630291; called by muse, mutect2, varscan2
- IGHV2-70 | c.310A>T p.T104S | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (1); PolyPhen probably damaging (0.989); catalogued as rs368647772; called by muse, varscan2
- IGHV2-70 | c.155del p.G52Efs*4 | Frame Shift Del (DEL) | VAF 46/102 reads (45%) | catalogued as rs757190616; called by pindel, varscan2
- IGHV2-70 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as rs534553794; called by muse, varscan2
- IGLV3-1 | c.97C>G p.P33A | Missense Mutation (SNP) | VAF 64/149 reads (43%) | SIFT tolerated (0.76); PolyPhen benign (0.166); catalogued as rs573884769; called by muse, mutect2, varscan2
- MAGEL2 | c.3559C>T p.R1187* | Nonsense Mutation (SNP) | VAF 107/184 reads (58%) | catalogued as rs368965952, COSV100045884, COSV100046025; called by muse, mutect2, varscan2
- MAP1A | c.2592G>C p.K864N | Missense Mutation (SNP) | VAF 55/244 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100288595; called by muse, mutect2, varscan2
- MATN2 | c.799G>A p.G267S | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1266765851; called by muse, mutect2
- MUC12 | c.394C>T p.L132F | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated, low confidence (0.06); catalogued as rs1256983713; called by muse, mutect2, varscan2
- MYCBP2 | c.12823G>A p.D4275N (on ENST00000357337; = p.D4313N on NM_015057.5) | Missense Mutation (SNP) | VAF 114/132 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62044146; called by muse, mutect2, varscan2
- NCAPG2 | c.2579C>G p.S860C | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.524); catalogued as rs1334499369; called by muse, mutect2
- NUP214 | c.3295C>T p.R1099W | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1303316975; called by muse, mutect2, varscan2
- PARP14 | c.4402G>A p.D1468N | Missense Mutation (SNP) | VAF 56/231 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs564004211; called by muse, mutect2, varscan2
- PDCD11 | c.4291G>C p.G1431R | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV63932868; called by muse, mutect2, varscan2
- PLXNB1 | c.3817C>T p.R1273C | Missense Mutation (SNP) | VAF 67/252 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs777440373, COSV56486750; called by muse, mutect2, varscan2
- PPP1R3C | c.60G>A p.M20I | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs765370918; called by muse, mutect2, varscan2
- PTPRC | c.1565T>C p.V522A | Missense Mutation (SNP) | VAF 65/241 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.11); catalogued as rs762391496, COSV100723348; called by muse, mutect2, varscan2
- RAB10 | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 34/419 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.063); catalogued as rs149788536; called by muse, mutect2
- RINL | c.1499T>C p.F500S (on ENST00000591812 / NM_001195833.2; = p.F386S on NM_198445.4) | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758854340; called by muse, varscan2
- RYR3 | c.4118A>T p.D1373V | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755136349; called by muse, mutect2, varscan2
- SLC1A5 | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778524513; called by muse, mutect2, varscan2
- SNTG2 | c.1606A>G p.M536V | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs371161023; called by muse, mutect2, varscan2
- SVOPL | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.69); catalogued as rs139868586; called by muse, mutect2, varscan2
- TRABD | c.672C>T p.S224= | Splice Region (SNP) | VAF 37/92 reads (40%) | catalogued as rs763947053; called by muse, mutect2, varscan2
- TRRAP | c.5867C>T p.T1956I (on ENST00000359863 / NM_001244580.1; = p.T1938I on NM_003496.3) | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs782485850; called by muse, mutect2, varscan2
- UEVLD | c.305A>G p.H102R | Missense Mutation (SNP) | VAF 63/211 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1308377012; called by muse, mutect2, varscan2
- WNK3 | c.3440C>T p.S1147F | Missense Mutation (SNP) | VAF 67/83 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV63614176; called by muse, mutect2, varscan2
- ZNF679 | c.1210G>T p.G404* | Nonsense Mutation (SNP) | VAF 52/127 reads (41%) | catalogued as COSV55378362; called by muse, mutect2, varscan2
- ZNF679 | c.1211G>T p.G404V | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99738433; called by muse, mutect2, varscan2
- ZNF7 | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 214/240 reads (89%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as rs1319987786; called by muse, mutect2, varscan2
- A2ML1 | c.1144G>C p.G382R | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ABCA4 | c.4783A>T p.T1595S | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.9); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACSM2B | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AFF2 | c.2105A>T p.K702M | Missense Mutation (SNP) | VAF 67/88 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- AGFG2 | c.633G>C p.Q211H | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ALLC | c.55T>C p.F19L | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- ANKRD17 | c.4779C>G p.Y1593* | Nonsense Mutation (SNP) | VAF 45/104 reads (43%) | called by muse, mutect2, varscan2
- APH1A | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- ARHGAP11A | c.766G>C p.D256H | Missense Mutation (SNP) | VAF 130/815 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- B4GALT6 | c.354C>A p.F118L | Missense Mutation (SNP) | VAF 86/146 reads (59%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- CATSPERG | c.1839G>A p.M613I | Missense Mutation (SNP) | VAF 73/246 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CCDC142 | c.1744G>A p.A582T (on ENST00000393965 / NM_001365575.2; = p.A575T on NM_032779.4) | Missense Mutation (SNP) | VAF 19/346 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- CCL4L2 | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 7/223 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2
- CD207 | c.122C>G p.T41R | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- CHD1 | c.669A>T p.E223D | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLK3 | c.1750C>T p.L584F (on ENST00000395066 / NM_001130028.1; = p.L436F on NM_003992.4) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- CMYA5 | c.9854A>T p.K3285M | Missense Mutation (SNP) | VAF 85/185 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- COL18A1 | c.2493+2T>G p.X831_splice (on ENST00000359759 / NM_130444.3; = p.X596_splice on NM_030582.4) | Splice Site (SNP) | VAF 58/177 reads (33%) | called by muse, mutect2, varscan2
- CTNNA2 | c.1286T>A p.V429E | Missense Mutation (SNP) | VAF 56/185 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, varscan2
- CTSK | c.189G>T p.E63D | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- CTSV | c.113G>A p.R38K | Missense Mutation (SNP) | VAF 77/271 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DCAF12 | c.229A>T p.S77C | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- DNAH9 | c.721T>G p.L241V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.082); called by muse, mutect2
- DNAJC13 | c.1188_1190del p.F396_S397delinsL | In Frame Del (DEL) | VAF 35/129 reads (27%) | called by mutect2, pindel, varscan2
- DPYSL3 | c.619C>T p.Q207* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | called by muse, varscan2
- DRAXIN | c.200G>C p.W67S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DSC2 | c.1109A>C p.D370A | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- DUSP7 | c.419C>T p.T140M | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- F13A1 | c.1676C>T p.T559I | Missense Mutation (SNP) | VAF 44/227 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- F8 | c.5391G>T p.Q1797H | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT tolerated (0.12); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- FRYL | c.1204A>G p.T402A | Missense Mutation (SNP) | VAF 71/154 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- FUS | c.811C>T p.Q271* | Nonsense Mutation (SNP) | VAF 16/112 reads (14%) | called by muse, mutect2, varscan2
- GNPAT | c.1288C>A p.P430T | Missense Mutation (SNP) | VAF 66/321 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HDAC5 | c.2842A>T p.I948F | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HK1 | c.1265A>G p.Q422R | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT tolerated (0.88); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- HLA-DPB1 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- IGHV2-70D | c.347G>A p.C116Y | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- IGKV4-1 | c.136del p.S46Afs*14 | Frame Shift Del (DEL) | VAF 30/57 reads (53%) | called by pindel, varscan2
- INTS10 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- KBTBD3 | c.1516C>A p.P506T | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- KLHDC7B | c.1573C>T p.P525S (on ENST00000395676; = p.P1166S on NM_138433.5) | Missense Mutation (SNP) | VAF 69/140 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- LRIF1 | c.338A>G p.D113G | Missense Mutation (SNP) | VAF 75/203 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- LRP2 | c.8088T>A p.N2696K | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- LRTOMT | c.125del p.K42Sfs*9 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | called by mutect2, pindel, varscan2
- LRWD1 | c.1625T>G p.V542G | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MACF1 | c.19546G>T p.V6516F (on ENST00000372915; = p.V4561F on NM_012090.5) | Missense Mutation (SNP) | VAF 13/244 reads (5%) | called by muse, mutect2
- MACROD1 | c.930C>A p.D310E | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- MYH4 | c.2754A>T p.Q918H | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NARF | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NECAP1 | c.167C>G p.A56G | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- NUP98 | c.3081T>A p.C1027* (on ENST00000359171 / NM_001365126.1; = p.C1010* on NM_016320.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 71/213 reads (33%) | called by muse, mutect2, varscan2
- NYAP1 | c.592del p.R198Gfs*5 | Frame Shift Del (DEL) | VAF 58/224 reads (26%) | called by mutect2, pindel, varscan2
- OSMR | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PAPLN | c.2773C>T p.Q925* (on ENST00000554301; = p.Q898* on NM_173462.4) | Nonsense Mutation (SNP) | VAF 31/79 reads (39%) | called by muse, mutect2, varscan2
- PCDHGA5 | c.1770G>T p.K590N | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PGAM5 | c.507A>T p.K169N | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- PKHD1L1 | c.12017G>A p.S4006N | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLCB1 | c.2486del p.A829Vfs*2 | Frame Shift Del (DEL) | VAF 77/220 reads (35%) | called by mutect2, pindel, varscan2
- POLE | c.1886C>T p.A629V | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPIC | c.463_478del p.W155Mfs*11 | Frame Shift Del (DEL) | VAF 26/101 reads (26%) | called by mutect2, pindel, varscan2
- PRLH | c.47T>A p.L16Q | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- PYDC2 | c.281T>C p.M94T | Missense Mutation (SNP) | VAF 114/429 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RAB11FIP3 | c.835G>A p.V279I | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RABEP2 | c.949C>A p.Q317K | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- RGSL1 | c.626A>G p.H209R | Missense Mutation (SNP) | VAF 151/236 reads (64%) | SIFT tolerated (0.74); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- RINL | c.1504dup p.A502Gfs*51 (on ENST00000591812 / NM_001195833.2; = p.A388Gfs*51 on NM_198445.4) | Frame Shift Ins (INS) | VAF 36/100 reads (36%) | called by pindel, varscan2
- RNF217-AS1 | n.384T>G | Splice Region (SNP) | VAF 78/154 reads (51%) | called by muse, mutect2, varscan2
- SCN4A | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- SCN5A | c.33C>G p.S11R | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- SEPTIN8 | c.1311G>T p.Q437H | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- SERPINB1 | c.880C>T p.Q294* | Nonsense Mutation (SNP) | VAF 183/263 reads (70%) | called by muse, mutect2, varscan2
- SHROOM4 | c.2216C>A p.A739E | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT tolerated (0.25); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SIAH2 | c.257A>C p.Y86S | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- SLC37A1 | c.959_973del p.F320_K325delins* | Nonsense Mutation (DEL) | VAF 15/64 reads (23%) | called by mutect2, pindel, varscan2
- SRRM4 | c.968A>T p.N323I | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2
- TGIF1 | c.611del p.P204Qfs*30 (on ENST00000330513 / NM_001374396.1; = p.P224Qfs*30 on NM_003244.4) | Frame Shift Del (DEL) | VAF 88/334 reads (26%) | called by mutect2, pindel, varscan2
- TIPARP | c.1948G>C p.E650Q | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); called by muse, varscan2
- TLR5 | c.507G>T p.L169F | Missense Mutation (SNP) | VAF 21/275 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMCC2 | c.2084G>A p.W695* | Nonsense Mutation (SNP) | VAF 18/290 reads (6%) | called by muse, mutect2
- TNS1 | c.4106C>T p.S1369F | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TP53 | c.894_910del p.E298Dfs*2 | Frame Shift Del (DEL) | VAF 70/204 reads (34%) | called by pindel, varscan2
- TRMT11 | c.113C>A p.A38D | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSC22D1 | c.3055C>G p.Q1019E (on ENST00000458659 / NM_183422.4; = p.Q90E on NM_006022.4) | Missense Mutation (SNP) | VAF 30/34 reads (88%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- TSPAN19 | c.296T>C p.V99A | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- TYW1 | c.499del p.T167Lfs*3 | Frame Shift Del (DEL) | VAF 90/269 reads (33%) | called by mutect2, pindel, varscan2
- UBXN10 | c.752T>A p.F251Y | Missense Mutation (SNP) | VAF 73/262 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- USP43 | c.190G>C p.A64P | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- XPOT | c.1168A>G p.N390D | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.015); called by muse, mutect2
- ZAP70 | c.1329C>A p.H443Q | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBTB16 | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 59/239 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- ZBTB21 | c.3000_3001delinsT p.E1000Dfs*97 | Frame Shift Del (DEL) | VAF 29/150 reads (19%) | called by pindel, varscan2*
- ZBTB26 | c.1275A>T p.K425N | Missense Mutation (SNP) | VAF 63/194 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ZC3H12D | c.802T>A p.Y268N | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZFHX4 | c.355T>A p.L119I | Missense Mutation (SNP) | VAF 15/282 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.225); called by muse, mutect2
- ZNF3 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ZNF415 | c.688C>G p.H230D | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF605 | c.1235A>G p.Q412R | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ZNF611 | c.1570A>T p.S524C | Missense Mutation (SNP) | VAF 64/240 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF727 | c.505A>T p.R169* | Nonsense Mutation (SNP) | VAF 64/167 reads (38%) | called by muse, mutect2, varscan2
- ZNF880 | c.632C>G p.P211R | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ZSCAN32 | c.10G>T p.V4L (on ENST00000396846; = p.V5L on NM_001284527.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 101/214 reads (47%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- ACTL7B | c.1194C>A p.V398= | Silent (SNP) | VAF 5/86 reads (6%) | called by muse, mutect2
- ADAM29 | c.1143G>A p.R381= | Silent (SNP) | VAF 54/155 reads (35%) | called by muse, mutect2, varscan2
- AHCTF1 | c.2196T>G p.P732= (on ENST00000366508; = p.P706= on NM_015446.5) | Silent (SNP) | VAF 10/39 reads (26%) | called by muse, mutect2
- ALG2 | c.420A>T p.P140= | Silent (SNP) | VAF 50/151 reads (33%) | called by muse, mutect2, varscan2
- ANKRD27 | c.2352C>T p.A784= | Silent (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- AQR | c.4248C>T p.D1416= | Silent (SNP) | VAF 71/427 reads (17%) | called by muse, mutect2, varscan2
- ATF3 | c.330G>A p.K110= | Silent (SNP) | VAF 30/97 reads (31%) | called by muse, mutect2, varscan2
- CCNK | c.1374C>T p.Y458= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs757619350; called by muse, mutect2, varscan2
- CHD5 | c.4506C>A p.T1502= | Silent (SNP) | VAF 36/117 reads (31%) | catalogued as COSV99312138; called by muse, mutect2, varscan2
- CHRM4 | c.351C>T p.N117= | Silent (SNP) | VAF 73/259 reads (28%) | catalogued as rs200711711, COSV63126667; called by muse, mutect2, varscan2
- CLK3 | c.621G>A p.R207= (on ENST00000395066 / NM_001130028.1; = p.R59= on NM_003992.4) | Silent (SNP) | VAF 9/187 reads (5%) | catalogued as rs1474782450, COSV61414457; called by muse, mutect2
- COL9A1 | c.2106G>A p.K702= | Silent (SNP) | VAF 18/31 reads (58%) | catalogued as rs774146890, COSV57891804; ClinVar: likely benign; called by muse, mutect2, varscan2
- CYFIP1 | c.2490C>T p.H830= | Silent (SNP) | VAF 28/350 reads (8%) | called by muse, mutect2
- DIP2C | c.2523G>T p.V841= | Silent (SNP) | VAF 83/235 reads (35%) | catalogued as rs573371081; called by muse, mutect2, varscan2
- ECPAS | c.2424C>T p.C808= | Silent (SNP) | VAF 69/212 reads (33%) | called by muse, mutect2, varscan2
- EPB42 | c.1227C>A p.S409= (on ENST00000441366 / NM_001114134.2; = p.S439= on NM_000119.3) | Silent (SNP) | VAF 32/151 reads (21%) | called by muse, mutect2, varscan2
- ESPL1 | c.3639C>T p.S1213= | Silent (SNP) | VAF 108/223 reads (48%) | catalogued as rs753840797; called by muse, mutect2, varscan2
- FAM111A | c.663C>A p.I221= | Silent (SNP) | VAF 14/447 reads (3%) | called by muse, mutect2
- FBXL17 | c.732C>T p.D244= | Silent (SNP) | VAF 12/22 reads (55%) | called by muse, mutect2, varscan2
- FCRLB | c.1185A>G p.P395= | Silent (SNP) | VAF 103/346 reads (30%) | called by muse, mutect2, varscan2
- FUBP3 | c.1518G>A p.Q506= | Silent (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
- GEMIN4 | c.1875A>G p.L625= | Silent (SNP) | VAF 60/121 reads (50%) | catalogued as rs1283667429; called by muse, mutect2, varscan2
- GEMIN4 | c.333C>A p.I111= | Silent (SNP) | VAF 95/234 reads (41%) | called by muse, mutect2, varscan2
- GGT6 | c.732C>T p.G244= (on ENST00000574154 / NM_001122890.3; = p.G212= on NM_153338.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/103 reads (45%) | catalogued as rs373381271, COSV54593697; called by muse, mutect2, varscan2
- GML | c.88A>C p.R30= | Silent (SNP) | VAF 26/91 reads (29%) | called by muse, mutect2, varscan2
- HEY1 | c.580C>T p.L194= | Silent (SNP) | VAF 43/138 reads (31%) | called by muse, mutect2, varscan2
- HP | c.1068C>T p.G356= | Silent (SNP) | VAF 57/121 reads (47%) | catalogued as rs774808400; called by muse, mutect2, varscan2
- IGHV3-23 | c.24T>C p.L8= | Silent (SNP) | VAF 21/134 reads (16%) | catalogued as rs566916785; called by muse, varscan2
- IGKV4-1 | c.177A>G p.L59= | Silent (SNP) | VAF 56/70 reads (80%) | catalogued as rs551368026; called by muse, varscan2
- IRS1 | c.900C>A p.T300= | Silent (SNP) | VAF 13/122 reads (11%) | called by muse, mutect2, varscan2
- KISS1 | c.237G>T p.G79= | Silent (SNP) | VAF 18/87 reads (21%) | called by muse, mutect2, varscan2
- KMT5A | c.981G>A p.A327= | Silent (SNP) | VAF 72/161 reads (45%) | catalogued as rs199916420; called by muse, mutect2, varscan2
- LUC7L | c.171A>T p.G57= | Silent (SNP) | VAF 37/480 reads (8%) | called by muse, mutect2
- MAP3K10 | c.1782C>A p.G594= | Silent (SNP) | VAF 15/341 reads (4%) | catalogued as rs1308023106; called by muse, mutect2
- MPDU1 | c.576G>T p.L192= | Silent (SNP) | VAF 17/209 reads (8%) | called by muse, mutect2
- MR1 | c.633A>G p.K211= | Silent (SNP) | VAF 47/164 reads (29%) | called by muse, mutect2, varscan2
- NCMAP | c.120C>A p.V40= | Silent (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- NLGN1 | c.2164C>T p.L722= | Silent (SNP) | VAF 26/269 reads (10%) | catalogued as COSV100850541, COSV64326036; called by muse, mutect2, varscan2
- NSMCE1 | c.744G>A p.E248= | Silent (SNP) | VAF 64/167 reads (38%) | called by muse, mutect2, varscan2
- PCDHA8 | c.1629G>A p.P543= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as rs555722520, COSV65333069, COSV65333143; called by muse, mutect2, varscan2
- PHLDB1 | c.2832C>T p.H944= | Silent (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2
- PSG8 | c.324G>A p.L108= | Silent (SNP) | VAF 84/255 reads (33%) | catalogued as COSV100126544; called by muse, mutect2, varscan2
- PTCHD4 | c.729G>C p.L243= | Silent (SNP) | VAF 46/175 reads (26%) | called by muse, mutect2, varscan2
- RIMBP2 | c.2748A>T p.A916= | Silent (SNP) | VAF 38/95 reads (40%) | called by muse, mutect2, varscan2
- RXFP3 | c.102G>T p.A34= | Silent (SNP) | VAF 33/213 reads (15%) | called by muse, mutect2, varscan2
- SLC16A14 | c.1407A>G p.K469= | Silent (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
- SORBS3 | c.1323G>A p.E441= | Silent (SNP) | VAF 46/95 reads (48%) | called by muse, mutect2, varscan2
- UXS1 | c.585C>T p.A195= | Silent (SNP) | VAF 21/82 reads (26%) | called by muse, mutect2, varscan2
- ZC3H13 | c.3723G>T p.L1241= | Silent (SNP) | VAF 51/64 reads (80%) | called by muse, mutect2, varscan2
- AC108734.4 | n.1765G>T | RNA (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- ACOT8 | c.262+1341C>A | Intron (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- ADGRD2 | c.69-61G>A | Intron (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- AGR2 | c.*139T>A | 3'UTR (SNP) | VAF 9/93 reads (10%) | called by muse, mutect2
- AHSA2P | n.1510C>T | RNA (SNP) | VAF 11/63 reads (17%) | called by muse, mutect2, varscan2
- AIF1L | c.*2453C>T | 3'UTR (SNP) | VAF 30/85 reads (35%) | called by muse, mutect2, varscan2
- ALG10B | c.172-97C>T | Intron (SNP) | VAF 47/117 reads (40%) | called by muse, mutect2, varscan2
- AMD1 | c.*1004G>C | 3'UTR (SNP) | VAF 12/22 reads (55%) | called by muse, mutect2, varscan2
- ANKRD31 | c.104+32C>A | Intron (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
- AREL1 | c.482-1543C>T | Intron (SNP) | VAF 11/23 reads (48%) | catalogued as rs550438409; called by muse, mutect2, varscan2
- ARHGEF5 | c.*460C>T | 3'UTR (SNP) | VAF 29/110 reads (26%) | called by muse, mutect2, varscan2
- ATP13A5 | c.2159-21C>A | Intron (SNP) | VAF 28/105 reads (27%) | called by muse, mutect2, varscan2
- B2M | c.*351G>C | 3'UTR (SNP) | VAF 18/93 reads (19%) | called by muse, mutect2, varscan2
- B3GALT6 | c.*1017C>A | 3'UTR (SNP) | VAF 62/241 reads (26%) | called by muse, mutect2, varscan2
- BCAP29 | c.344+102G>A | Intron (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- BCL2 | c.*2491A>G | 3'UTR (SNP) | VAF 21/58 reads (36%) | catalogued as rs1009407487; called by muse, mutect2, varscan2
- BRCA1 | c.135-4013G>C | Intron (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- C22orf39 | c.*2944G>A | 3'UTR (SNP) | VAF 37/100 reads (37%) | called by muse, mutect2, varscan2
- C2orf91 | n.2245A>G | RNA (SNP) | VAF 38/130 reads (29%) | called by muse, mutect2, varscan2
- C7 | c.*547C>A | 3'UTR (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2
- CBX8 | c.*603C>T | 3'UTR (SNP) | VAF 32/81 reads (40%) | called by muse, mutect2, varscan2
- CCDC38 | c.37+1533C>T | Intron (SNP) | VAF 4/12 reads (33%) | catalogued as rs1019372914; called by muse, mutect2, varscan2
- CCNT2 | c.774+138C>T | Intron (SNP) | VAF 42/98 reads (43%) | called by muse, mutect2, varscan2
- CD1D | chr1:158177012 T>A | 5'Flank (SNP) | VAF 12/44 reads (27%) | called by mutect2, varscan2
- CEACAM19 | c.576-98C>A | Intron (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- CEACAM19 | c.576-97C>A | Intron (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- CHAF1B | c.*215C>T | 3'UTR (SNP) | VAF 22/45 reads (49%) | catalogued as rs571857716; called by muse, mutect2, varscan2
- CLDN18 | c.*1601C>T | 3'UTR (SNP) | VAF 12/58 reads (21%) | catalogued as rs1002704017; called by muse, mutect2, varscan2
- COL24A1 | c.*917G>C | 3'UTR (SNP) | VAF 40/95 reads (42%) | catalogued as rs1490456958; called by muse, mutect2, varscan2
- CPED1 | c.*190C>T | 3'UTR (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- CYFIP2 | chr5:157394442 G>A | 3'Flank (SNP) | VAF 37/110 reads (34%) | called by muse, mutect2, varscan2
- CYP2B7P | n.896G>T | RNA (SNP) | VAF 44/152 reads (29%) | called by muse, mutect2, varscan2
- DBF4B | c.1190-603G>A | Intron (SNP) | VAF 38/95 reads (40%) | called by muse, mutect2, varscan2
- DDX10 | c.2450+847A>G | Intron (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
- DDX19B | c.107-48del | Intron (DEL) | VAF 74/198 reads (37%) | called by mutect2, pindel, varscan2
- DEFB132 | c.*1387G>C | 3'UTR (SNP) | VAF 31/92 reads (34%) | called by muse, mutect2, varscan2
- DFFB | c.*1260A>G | 3'UTR (SNP) | VAF 27/114 reads (24%) | called by muse, mutect2, varscan2
- DLAT | c.*1123T>G | 3'UTR (SNP) | VAF 66/144 reads (46%) | called by muse, mutect2, varscan2
- DMTF1 | chr7:87152314 G>C | 5'Flank (SNP) | VAF 58/193 reads (30%) | called by muse, mutect2, varscan2
- DPYSL3 | c.-95C>A | 5'UTR (SNP) | VAF 19/38 reads (50%) | called by muse, mutect2, varscan2
- DRAXIN | c.*5826G>A | 3'UTR (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- DUSP7 | c.952+1339G>C | Intron (SNP) | VAF 32/125 reads (26%) | called by muse, mutect2, varscan2
- ELP1 | c.650-43A>T | Intron (SNP) | VAF 30/47 reads (64%) | called by muse, mutect2, varscan2
- EMX2 | c.*370G>T | 3'UTR (SNP) | VAF 32/120 reads (27%) | called by muse, mutect2, varscan2
- FAM189A1 | c.*125C>T | 3'UTR (SNP) | VAF 23/218 reads (11%) | called by muse, mutect2, varscan2
- FAM53C | c.*350T>G | 3'UTR (SNP) | VAF 50/118 reads (42%) | called by muse, mutect2, varscan2
- FAM98B | c.*1266_*1278del | 3'UTR (DEL) | VAF 10/124 reads (8%) | called by mutect2, pindel
- FBXL21P | n.1119A>G | RNA (SNP) | VAF 34/97 reads (35%) | called by muse, mutect2, varscan2
- FCER1G | c.*43C>T | 3'UTR (SNP) | VAF 114/409 reads (28%) | called by muse, mutect2, varscan2
- FKBP7 | c.*1845dup | 3'UTR (INS) | VAF 38/85 reads (45%) | called by mutect2, varscan2
- FOXC2 | c.*237G>A | 3'UTR (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2, varscan2
- FOXL2NB | c.*954C>T | 3'UTR (SNP) | VAF 35/147 reads (24%) | called by muse, mutect2, varscan2
- FOXRED1 | c.*173C>A | 3'UTR (SNP) | VAF 38/157 reads (24%) | catalogued as rs1478624812; called by muse, mutect2, varscan2
- FSCN3 | c.960+130T>C | Intron (SNP) | VAF 13/38 reads (34%) | called by muse, mutect2, varscan2
- FTO | c.*1800G>A | 3'UTR (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2, varscan2
- FUT4 | c.*417G>A | 3'UTR (SNP) | VAF 11/154 reads (7%) | called by muse, mutect2
- FYB1 | c.*1724G>T | 3'UTR (SNP) | VAF 11/65 reads (17%) | catalogued as rs939662187; called by muse, mutect2, varscan2
- FZD5 | c.*2276del | 3'UTR (DEL) | VAF 22/58 reads (38%) | called by mutect2, pindel, varscan2
- GABARAP | c.-119G>A | 5'UTR (SNP) | VAF 41/91 reads (45%) | catalogued as rs976912366; called by muse, varscan2
- GASK1A | c.-130C>T | 5'UTR (SNP) | VAF 23/57 reads (40%) | called by mutect2, varscan2
- GFOD1 | c.*6804C>T | 3'UTR (SNP) | VAF 53/194 reads (27%) | called by muse, mutect2, varscan2
- GNAI2 | c.*656G>C | 3'UTR (SNP) | VAF 10/141 reads (7%) | called by muse, mutect2
- GPX2 | chr14:64944476 G>A | 5'Flank (SNP) | VAF 21/46 reads (46%) | called by muse, mutect2, varscan2
- GUCY1A1 | c.*1797C>A | 3'UTR (SNP) | VAF 32/75 reads (43%) | called by muse, mutect2, varscan2
- GULP1 | c.399+50G>T | Intron (SNP) | VAF 35/72 reads (49%) | called by muse, mutect2, varscan2
- HGSNAT | c.*3211C>A | 3'UTR (SNP) | VAF 24/77 reads (31%) | called by muse, mutect2, varscan2
- HGSNAT | c.*3212C>A | 3'UTR (SNP) | VAF 24/77 reads (31%) | called by muse, mutect2, varscan2
- HMGCLL1 | c.*657T>A | 3'UTR (SNP) | VAF 35/95 reads (37%) | catalogued as rs929250304; called by muse, mutect2, varscan2
- HSPA12A | c.*2684A>T | 3'UTR (SNP) | VAF 23/93 reads (25%) | called by muse, mutect2, varscan2
- IFIT5 | c.*1184T>A | 3'UTR (SNP) | VAF 35/79 reads (44%) | called by muse, mutect2, varscan2
- IGHV3-23 | c.-75C>T | 5'UTR (SNP) | VAF 13/38 reads (34%) | called by muse, mutect2, varscan2
- IQCE | c.*2346G>T | 3'UTR (SNP) | VAF 41/124 reads (33%) | called by muse, mutect2, varscan2
- ITGAL | c.3229-65A>T | Intron (SNP) | VAF 28/112 reads (25%) | called by muse, mutect2, varscan2
- ITGB5 | c.*1178G>T | 3'UTR (SNP) | VAF 17/100 reads (17%) | called by muse, mutect2, varscan2
- JPT2 | c.*103A>T | 3'UTR (SNP) | VAF 14/334 reads (4%) | called by muse, mutect2
- KANSL1 | c.1289+63A>T | Intron (SNP) | VAF 31/122 reads (25%) | called by muse, mutect2, varscan2
- KBTBD12 | c.*3366G>A | 3'UTR (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- KBTBD4 | c.*128C>T | 3'UTR (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2, varscan2
- LINC02412 | n.1277T>A | RNA (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- LINS1 | c.*1344G>A | 3'UTR (SNP) | VAF 9/104 reads (9%) | called by muse, mutect2
- LPIN2 | c.*1607A>T | 3'UTR (SNP) | VAF 34/103 reads (33%) | called by muse, mutect2, varscan2
- LRRC15 | c.*1873_*1879del | 3'UTR (DEL) | VAF 32/160 reads (20%) | called by mutect2, pindel, varscan2
- LUZP2 | c.*3058A>T | 3'UTR (SNP) | VAF 23/53 reads (43%) | called by muse, mutect2, varscan2
- LY6G5C | c.346-885C>T | Intron (SNP) | VAF 60/197 reads (30%) | called by muse, mutect2, varscan2
- MACC1 | chr7:20139144 G>C | 3'Flank (SNP) | VAF 43/131 reads (33%) | called by muse, mutect2, varscan2
- MAP4 | c.1999+4309A>G | Intron (SNP) | VAF 66/218 reads (30%) | called by muse, mutect2, varscan2
- MATR3 | c.-157_-155del | 5'UTR (DEL) | VAF 10/28 reads (36%) | called by mutect2, pindel, varscan2
- MAU2 | c.*137C>G | 3'UTR (SNP) | VAF 92/424 reads (22%) | called by muse, mutect2, varscan2
- MFN2 | c.709-42C>A | Intron (SNP) | VAF 82/260 reads (32%) | catalogued as rs1181707568; called by muse, varscan2
- MS4A14 | c.267+68T>A | Intron (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2, varscan2
- MTBP | chr8:120445371 T>G | 5'Flank (SNP) | VAF 23/63 reads (37%) | called by muse, mutect2, varscan2
- MTRF1L | c.*2484del | 3'UTR (DEL) | VAF 107/324 reads (33%) | called by mutect2, pindel, varscan2
- MVB12B | c.*2383G>T | 3'UTR (SNP) | VAF 23/38 reads (61%) | called by muse, mutect2, varscan2
- MYO3A | c.732-599C>T | Intron (SNP) | VAF 28/85 reads (33%) | called by muse, mutect2, varscan2
- MYO5C | c.4043-170C>T | Intron (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- NDST1 | c.*3186C>T | 3'UTR (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- NSD2 | c.2014-52G>A | Intron (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- NSF | c.*747A>T | 3'UTR (SNP) | VAF 11/98 reads (11%) | called by muse, mutect2
- NT5DC2 | c.121+126C>G | Intron (SNP) | VAF 11/31 reads (35%) | called by muse, mutect2, varscan2
- NT5DC2 | c.121+125C>A | Intron (SNP) | VAF 11/31 reads (35%) | catalogued as rs1219786417; called by muse, mutect2, varscan2
- ONECUT2 | c.*11750dup | 3'UTR (INS) | VAF 17/54 reads (31%) | called by mutect2, varscan2
- OR7E24 | c.*5G>T | 3'UTR (SNP) | VAF 31/277 reads (11%) | called by muse, mutect2, varscan2
- PAK1IP1 | c.-7C>G | 5'UTR (SNP) | VAF 51/221 reads (23%) | called by muse, mutect2, varscan2
- PAPOLB | c.*1233A>G | 3'UTR (SNP) | VAF 34/98 reads (35%) | called by muse, mutect2, varscan2
- PAQR6 | c.760+39G>A | Intron (SNP) | VAF 34/157 reads (22%) | called by muse, mutect2, varscan2
- PARP8 | c.*400T>A | 3'UTR (SNP) | VAF 15/74 reads (20%) | called by muse, mutect2, varscan2
- PDE4D | c.456-59882C>A | Intron (SNP) | VAF 43/117 reads (37%) | called by muse, mutect2, varscan2
- PDIA4 | c.*590G>A | 3'UTR (SNP) | VAF 49/160 reads (31%) | called by muse, mutect2, varscan2
- PDZRN4 | c.*106_*109del | 3'UTR (DEL) | VAF 37/171 reads (22%) | called by mutect2, pindel, varscan2
- PEG10 | c.*4798G>T | 3'UTR (SNP) | VAF 24/96 reads (25%) | called by muse, mutect2, varscan2
- PIK3R3 | c.*3382T>C | 3'UTR (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- PKNOX2 | c.*66G>A | 3'UTR (SNP) | VAF 21/95 reads (22%) | catalogued as rs879203288, COSV100021397; called by muse, mutect2, varscan2
- PLCD3 | c.1712-58G>C | Intron (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- PLOD2 | c.*89G>A | 3'UTR (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- PPP1R9A | c.*2792A>G | 3'UTR (SNP) | VAF 5/33 reads (15%) | catalogued as rs964246763; called by muse, mutect2, varscan2
- PRKD1 | c.*714T>C | 3'UTR (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- PSMG4 | c.251-1210T>C | Intron (SNP) | VAF 54/174 reads (31%) | called by muse, mutect2, varscan2
- PTEN | c.*3989G>T | 3'UTR (SNP) | VAF 34/82 reads (41%) | called by muse, mutect2, varscan2
- PTGR1 | c.209+194C>A | Intron (SNP) | VAF 58/325 reads (18%) | called by muse, mutect2, varscan2
- PXDN | c.1947-110del | Intron (DEL) | VAF 10/26 reads (38%) | called by mutect2, pindel, varscan2
- RBM24 | c.169-435G>T | Intron (SNP) | VAF 32/115 reads (28%) | called by muse, mutect2, varscan2
- RGS16 | c.*1606A>C | 3'UTR (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- RPS27 | c.116-44_116-43dup | Intron (INS) | VAF 23/94 reads (24%) | called by mutect2, pindel, varscan2
- RRM2B | c.*1033del | 3'UTR (DEL) | VAF 20/78 reads (26%) | called by mutect2, pindel, varscan2
- RTN3 | c.*532T>C | 3'UTR (SNP) | VAF 33/245 reads (13%) | called by muse, mutect2, varscan2
- RUFY3 | c.*1295T>G | 3'UTR (SNP) | VAF 16/38 reads (42%) | catalogued as rs961617856; called by muse, mutect2, varscan2
- SCN5A | c.*9C>A | 3'UTR (SNP) | VAF 7/50 reads (14%) | catalogued as COSV100346771; called by muse, mutect2, varscan2
- SESN3 | c.*5181A>G | 3'UTR (SNP) | VAF 26/94 reads (28%) | called by muse, mutect2, varscan2
- SEZ6L | c.*1346C>G | 3'UTR (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
- SGK1 | c.-266C>A | 5'UTR (SNP) | VAF 81/168 reads (48%) | called by muse, mutect2, varscan2
- SKP1 | c.457-241G>A | Intron (SNP) | VAF 92/233 reads (39%) | called by muse, mutect2, varscan2
- SLC30A7 | c.-2_1del | 5'UTR (DEL) | VAF 74/174 reads (43%) | catalogued as rs976431646; called by pindel, varscan2
- SLC44A1 | c.*5794C>T | 3'UTR (SNP) | VAF 53/157 reads (34%) | catalogued as rs886283955; called by muse, mutect2, varscan2
- SLC5A12 | c.1153+726T>G | Intron (SNP) | VAF 41/62 reads (66%) | called by muse, mutect2, varscan2
- SMAD9 | c.*2054C>T | 3'UTR (SNP) | VAF 30/33 reads (91%) | called by muse, mutect2, varscan2
- SMARCAD1 | c.*28G>A | 3'UTR (SNP) | VAF 58/194 reads (30%) | catalogued as rs1255919349; called by muse, varscan2
- SMU1 | c.-34G>C | 5'UTR (SNP) | VAF 202/614 reads (33%) | called by muse, varscan2
- SMUG1 | c.285+507G>C | Intron (SNP) | VAF 47/122 reads (39%) | called by muse, mutect2, varscan2
- SNX15 | c.*642G>T | 3'UTR (SNP) | VAF 14/59 reads (24%) | called by muse, mutect2, varscan2
- SNX20 | chr16:50667419 C>A | 3'Flank (SNP) | VAF 105/241 reads (44%) | called by muse, mutect2, varscan2
- SOX2 | c.-33C>T | 5'UTR (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- SP7 | c.*937C>T | 3'UTR (SNP) | VAF 26/84 reads (31%) | called by muse, mutect2, varscan2
- SPATA8 | n.259C>A | RNA (SNP) | VAF 17/68 reads (25%) | called by muse, mutect2, varscan2
- SPICE1 | c.*1336G>T | 3'UTR (SNP) | VAF 15/65 reads (23%) | called by muse, mutect2, varscan2
- SPX | c.*128C>T | 3'UTR (SNP) | VAF 57/119 reads (48%) | called by muse, mutect2, varscan2
- SRPRA | c.365+14C>G | Intron (SNP) | VAF 43/83 reads (52%) | called by muse, mutect2, varscan2
- ST3GAL4 | c.*120G>A | 3'UTR (SNP) | VAF 6/120 reads (5%) | called by muse, mutect2
- SYT10 | c.*124G>A | 3'UTR (SNP) | VAF 27/81 reads (33%) | called by muse, mutect2, varscan2
- TAS2R9 | c.-87G>C | 5'UTR (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2, varscan2
- TCP10L3 | n.2618+454A>C | Intron (SNP) | VAF 20/62 reads (32%) | called by muse, varscan2
- TFEC | c.*656A>C | 3'UTR (SNP) | VAF 25/89 reads (28%) | called by muse, mutect2, varscan2
- TMEM109 | c.*222T>G | 3'UTR (SNP) | VAF 58/256 reads (23%) | catalogued as rs1417820397; called by muse, mutect2, varscan2
- TMEM132D | c.-48G>A | 5'UTR (SNP) | VAF 30/72 reads (42%) | called by muse, mutect2, varscan2
- TMEM170B | c.-33del | 5'UTR (DEL) | VAF 7/52 reads (13%) | called by mutect2, pindel, varscan2
- TMTC4 | c.778-75G>T | Intron (SNP) | VAF 52/60 reads (87%) | called by muse, mutect2, varscan2
- TPD52L3 | c.*1321G>T | 3'UTR (SNP) | VAF 30/95 reads (32%) | called by muse, mutect2, varscan2
- TRAK1 | c.1963+638G>A | Intron (SNP) | VAF 24/93 reads (26%) | called by muse, mutect2, varscan2
- TRIM24 | c.*162T>C | 3'UTR (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2, varscan2
- TRPV3 | c.*1542C>T | 3'UTR (SNP) | VAF 16/64 reads (25%) | called by muse, mutect2
- TRUB1 | c.*119A>T | 3'UTR (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- TSC1 | c.*3619G>T | 3'UTR (SNP) | VAF 66/252 reads (26%) | called by muse, mutect2, varscan2
- TTL | c.*2829_*2831delinsAA | 3'UTR (DEL) | VAF 50/180 reads (28%) | called by pindel, varscan2*
- UQCRH | c.*26C>T | 3'UTR (SNP) | VAF 106/246 reads (43%) | catalogued as rs989359535; called by muse, mutect2, varscan2
- USF3 | c.*5843C>T | 3'UTR (SNP) | VAF 25/76 reads (33%) | catalogued as rs1158333276; called by muse, mutect2, varscan2
- USF3 | c.*5592G>C | 3'UTR (SNP) | VAF 34/135 reads (25%) | catalogued as rs1376797461; called by muse, mutect2, varscan2
- UVSSA | c.*7603G>A | 3'UTR (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- Unknown | chr7:55707300 G>T | IGR (SNP) | VAF 42/268 reads (16%) | called by muse, mutect2, varscan2
- VGLL3 | c.*3330G>A | 3'UTR (SNP) | VAF 25/82 reads (30%) | called by muse, mutect2, varscan2
- XCL1 | c.*624del | 3'UTR (DEL) | VAF 19/116 reads (16%) | called by mutect2, pindel, varscan2
- YARS1 | c.*558C>T | 3'UTR (SNP) | VAF 44/121 reads (36%) | called by muse, mutect2, varscan2
- ZNF700 | c.*497G>T | 3'UTR (SNP) | VAF 18/65 reads (28%) | called by muse, mutect2, varscan2
- ZNF813 | c.*3433T>A | 3'UTR (SNP) | VAF 20/92 reads (22%) | called by muse, mutect2, varscan2
- ZSCAN29 | c.*2276C>T | 3'UTR (SNP) | VAF 37/160 reads (23%) | called by muse, mutect2, varscan2
